Somatic mutation profile of tumor specimen TCGA-FB-AAQ3-01A (aliquot TCGA-FB-AAQ3-01A-11D-A40W-08) from TCGA case TCGA-FB-AAQ3, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 65.6 years (23,953 days).
Specimen TCGA-FB-AAQ3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41869091-1d06-49fe-8dcf-2f7008202f78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAQ3-11A (Solid Tissue Normal), aliquot TCGA-FB-AAQ3-11A-11D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c70f389b-b2d6-49d7-8702-dff2dc8c55e8

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 33/242 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC008397.2 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV99441524; called by muse, mutect2, varscan2
- APBA2 | c.951G>T p.Q317H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); catalogued as COSV101382113; called by muse, mutect2
- CILP2 | c.3322C>T p.P1108S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99364562; called by muse, mutect2, varscan2
- DOCK1 | c.4504G>A p.D1502N | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs369052092; called by muse, mutect2, varscan2
- EEF2 | c.2447A>T p.H816L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100500687; called by muse, mutect2
- EEPD1 | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV99632087; called by muse, mutect2, varscan2
- EML1 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99214835, COSV99215017; called by muse, mutect2, varscan2
- ERN2 | c.2727C>G p.Y909* | Nonsense Mutation (SNP) | VAF 30/207 reads (14%) | catalogued as COSV99891237; called by muse, mutect2, varscan2
- FAM13B | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 82/534 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs375616241; called by muse, mutect2, varscan2
- FIGN | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 90/521 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs766943714, COSV104411568, COSV60764351; called by muse, mutect2, varscan2
- FZD10 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as rs778587255, COSV57474364, COSV57474947, COSV99969362; called by muse, mutect2, varscan2
- H2AC6 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100019863, COSV58417094; called by muse, mutect2, varscan2
- LATS1 | c.3007G>T p.E1003* | Nonsense Mutation (SNP) | VAF 128/528 reads (24%) | catalogued as COSV99485731; called by muse, mutect2, varscan2
- MACF1 | c.3903G>A p.M1301I | Missense Mutation (SNP) | VAF 19/181 reads (10%) | catalogued as COSV100482987, COSV100483846; called by muse, mutect2, varscan2
- MCF2 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 82/487 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs766972582, COSV58483217; called by muse, mutect2, varscan2
- MED13L | c.5514G>T p.W1838C | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56117194, COSV99928501; called by muse, mutect2, varscan2
- METTL25 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as rs747731767, COSV99810639; called by muse, mutect2, varscan2
- NLGN4X | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1178890314, COSV52037352; called by muse, mutect2
- OR5P2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 107/575 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147652902; called by muse, mutect2, varscan2
- OTOGL | c.1881T>A p.D627E (on ENST00000547103; = p.D618E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101509156; called by muse, mutect2, varscan2
- PCDHGB7 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191453038, COSV99535784; called by muse, mutect2
- PEG3 | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 83/450 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs1194431417, COSV99688441; called by muse, mutect2, varscan2
- PI15 | c.683C>A p.P228Q | Missense Mutation (SNP) | VAF 118/698 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs896102142, COSV99477952; called by muse, mutect2, varscan2
- PPFIA2 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV100332808; called by muse, mutect2
- SNCAIP | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV99748251; called by muse, mutect2, varscan2
- TEFM | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 102/723 reads (14%) | catalogued as COSV100035074; called by muse, mutect2, varscan2
- TP53 | c.532dup p.H178Pfs*3 | Frame Shift Ins (INS) | VAF 47/243 reads (19%) | catalogued as COSV99408054; called by mutect2, pindel, varscan2
- HPSE2 | c.669del p.F223Lfs*3 | Frame Shift Del (DEL) | VAF 61/336 reads (18%) | called by mutect2, pindel, varscan2
- LTB4R2 | c.110G>A p.R37H (on ENST00000528054; = p.R6H on NM_019839.5) | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2
- THBS4 | c.261dup p.E88* | Frame Shift Ins (INS) | VAF 32/246 reads (13%) | called by mutect2, pindel, varscan2
- AJAP1 | c.1053C>T p.N351= | Silent (SNP) | VAF 22/188 reads (12%) | catalogued as rs770867069, COSV100981609; called by muse, mutect2, varscan2
- AVP | c.57G>A p.A19= | Silent (SNP) | VAF 142/792 reads (18%) | catalogued as rs779598962, COSV66671834; called by muse, mutect2, varscan2
- INPP4B | c.2169C>T p.A723= | Silent (SNP) | VAF 106/612 reads (17%) | catalogued as rs376859157; called by muse, mutect2, varscan2
- MAGEB1 | c.591G>A p.R197= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs1334505269, COSV100974924; called by muse, mutect2, varscan2
- OR1L1 | c.252C>A p.I84= (on ENST00000373686; = p.I34= on NM_001005236.3) | Silent (SNP) | VAF 66/345 reads (19%) | catalogued as COSV100542118; called by muse, mutect2, varscan2
- PCDHA8 | c.2358C>T p.G786= | Silent (SNP) | VAF 44/251 reads (18%) | catalogued as rs370299201, COSV100969373; called by muse, mutect2, varscan2
- PLXNC1 | c.3582G>T p.P1194= | Silent (SNP) | VAF 132/874 reads (15%) | catalogued as COSV99312901; called by mutect2, varscan2
- PRAF2 | c.156C>T p.F52= | Silent (SNP) | VAF 72/307 reads (23%) | catalogued as rs782154900, COSV59875551; called by muse, mutect2, varscan2
- PRDM13 | c.1422G>A p.P474= | Silent (SNP) | VAF 56/278 reads (20%) | catalogued as rs377013141; called by muse, mutect2, varscan2
- WNT10B | c.990G>A p.R330= | Silent (SNP) | VAF 37/196 reads (19%) | catalogued as COSV99975894; called by muse, mutect2, varscan2
- ELK4 | c.1080+35T>G | Intron (SNP) | VAF 43/205 reads (21%) | catalogued as COSV99222318; called by muse, mutect2, varscan2
